Somatic mutation profile of tumor specimen 0DWGJX from CCDI case PBCNRH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 2.0 years (729 days).
Specimen 0DWGJX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e1e5a59-b548-46f8-87a6-577072e75b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWGJ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/377b7898-7f68-4511-bfc1-0dae9b5ec265

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Splice Site 1, Frame Shift Del 1, Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMCN2 | c.7957G>A p.G2653S | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as rs914354068; called by muse, mutect2, varscan2
- COL6A5 | c.2208_2217del p.D737Rfs*5 | Frame Shift Del (DEL) | VAF 32/339 reads (9%) | called by mutect2, pindel
- GLS | c.979+1G>T p.X327_splice | Splice Site (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- CEP170 | c.*87C>A | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- GYG2 | c.-72C>T | 5'UTR (SNP) | VAF 53/64 reads (83%) | called by muse, mutect2, varscan2
